Gene-level copy-number profile of tumor specimen TCGA-WE-A8ZM-06A from TCGA case TCGA-WE-A8ZM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.8 years (28,047 days).
Specimen TCGA-WE-A8ZM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7b570927-85c8-4f6b-b4af-6c74e3af25b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8ZM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d8e8938b-6179-42c9-a0c2-73bc48632af5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 228; copy number 2: 12,916; copy number 3: 11,621; copy number 4: 25,387; copy number 5: 2,733; copy number 6: 3,298; copy number 7: 224; copy number 8: 923; copy number 9: 2,188; copy number 11: 187; copy number 12: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8ZM-06A-11D-A371-01): tumor purity 0.85, ploidy 3.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,522,666–181,700,142, 3 genes: AC093840.1, AC093840.2, AC084741.1.
- chr5:138,946,724–139,293,557, 4 genes (within-gene range 0–2): SIL1, RNA5SP194, AC011405.1, RPL12P21.
- chr9:21,966,929–22,128,103, 8 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:73,995,193–74,121,363, 1 gene (within-gene range 0–2): VCL.
- chr10:74,120,255–74,150,842, 1 gene: AP3M1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,444 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:9,621,764–9,769,513, 1 gene, copy number 9 (within-gene range 6–9): AC060834.2.
- chr7:9,726,241–63,176,019, 875 genes, copy number 9 (broad region; genes not listed).
- chr8:46,028,804–137,092,183, 1,312 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr15:67,542,703–71,053,658, 69 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr15:72,266,746–77,820,900, 187 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
